Somatic mutation profile of tumor specimen ALCH-B1RY-TTP1-A (aliquot ALCH-B1RY-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1RY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.5 years (21,736 days).
Specimen ALCH-B1RY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0c348b7-ea1f-4e1b-b36d-79aef3bdaab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RY-NB1-A (Blood Derived Normal), aliquot ALCH-B1RY-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/868f5792-3d25-4f58-85ff-c879eded0822

The open-access MAF lists 785 somatic variants for this specimen: 538 protein-altering or splice-affecting, 153 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 459, Silent 153, Intron 45, Nonsense Mutation 41, RNA 16, Splice Site 13, 3'UTR 12, 5'UTR 11, Frame Shift Del 11, Splice Region 8, 5'Flank 6, 3'Flank 4.

Variants (750 of 785; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 44/565 reads (8%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV52517971, COSV52518546; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 52/236 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 35/259 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UBE2A | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.416); catalogued as rs387906728, CM103007; ClinVar: pathogenic; called by muse, mutect2
- ABCD3 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV64644439; called by muse, mutect2, varscan2
- ACP7 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100488630; called by muse, mutect2, varscan2
- ADAM22 | c.1182C>G p.C394W | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715287; called by muse, mutect2
- ADGRL4 | c.633C>A p.D211E | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1399610988, COSV66061458; called by muse, mutect2
- ALOX5 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs560031203, COSV65550928; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.862); catalogued as rs770011324, COSV51839754; called by mutect2, varscan2
- APLP2 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.211); catalogued as rs371634970; called by muse, mutect2, varscan2
- APOA5 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57063062, COSV57065404; called by muse, mutect2, varscan2
- ARHGAP17 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 49/148 reads (33%) | catalogued as COSV51508309; called by muse, mutect2, varscan2
- BAHCC1 | c.5335C>T p.P1779S | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs782045563; called by muse, mutect2, varscan2
- BCLAF1 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV62141325, COSV62145613; called by mutect2, varscan2
- BCO1 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV50729874; called by muse, mutect2, varscan2
- BCOR | c.1982C>A p.P661Q | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV100653481; called by muse, mutect2
- BTN2A1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs1347712879; called by muse, mutect2
- C3orf18 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | catalogued as rs1226969855; called by muse, mutect2, varscan2
- C8B | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 61/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs144586148; called by muse, mutect2, varscan2
- CACNA1E | c.5243G>T p.W1748L | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62389591; called by muse, mutect2, varscan2
- CACNA1S | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 82/457 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs775158117; called by muse, mutect2, varscan2
- CACNA2D1 | c.2863C>T p.L955F (on ENST00000356253 / NM_001366867.1; = p.L943F on NM_000722.4) | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.123); catalogued as COSV62381154; called by muse, mutect2
- CASK | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.309); catalogued as rs1569376084, COSV59366168; ClinVar: uncertain significance; called by muse, mutect2
- CASP1 | c.1172G>T p.R391I (on ENST00000436863 / NM_033292.4; = p.R370I on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99507283; called by muse, mutect2, varscan2
- CATSPERE | c.2296G>T p.V766F | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1347058936; called by muse, mutect2, varscan2
- CCDC188 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.781); catalogued as rs564809212, COSV100273210; called by mutect2, varscan2
- CD53 | c.65T>A p.I22N | Missense Mutation (SNP) | VAF 31/375 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV54761091; called by muse, mutect2
- CDH7 | c.1765G>T p.G589C | Missense Mutation (SNP) | VAF 68/473 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59884694; called by muse, mutect2, varscan2
- CDH8 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54879094; called by muse, mutect2, varscan2
- CELSR3 | c.853C>A p.R285S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as rs1053309812; called by muse, mutect2, varscan2
- CFAP45 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 84/776 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs766454855, COSV63650277; called by muse, mutect2, varscan2
- CFAP52 | c.826T>C p.C276R | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as rs779089512; called by muse, mutect2, varscan2
- CHI3L2 | c.711A>T p.R237S | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.009); catalogued as rs1454625679; called by muse, mutect2, varscan2
- CNTLN | c.2129A>T p.K710I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV52076850; called by muse, mutect2, varscan2
- COMMD1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.762); catalogued as COSV61278718; called by muse, mutect2, varscan2
- COX7B2 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 9/97 reads (9%) | catalogued as COSV100261146; called by muse, mutect2
- CSMD1 | c.6067G>T p.E2023* (on ENST00000520002; = p.E2022* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 39/224 reads (17%) | catalogued as COSV59294475; called by muse, mutect2, varscan2
- CSMD3 | c.10057del p.E3353Kfs*19 (on ENST00000297405 / NM_001363185.1; = p.E3184Kfs*19 on NM_052900.3) | Frame Shift Del (DEL) | VAF 123/427 reads (29%) | catalogued as COSV52358313; called by mutect2, pindel, varscan2
- CSMD3 | c.6950C>A p.P2317H (on ENST00000297405 / NM_001363185.1; = p.P2213H on NM_052900.3) | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs1308655920; called by muse, mutect2
- CSMD3 | c.2879C>T p.P960L (on ENST00000297405 / NM_001363185.1; = p.P856L on NM_052900.3) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1439589330; called by muse, mutect2
- CSTF2 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880849; called by muse, mutect2
- CTSE | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 54/503 reads (11%) | catalogued as COSV100733633; called by muse, mutect2, varscan2
- CYTL1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.922); catalogued as rs200085707, COSV57036803; called by muse, mutect2, varscan2
- DAAM2 | c.1944G>C p.Q648H | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1349625062; called by muse, mutect2, varscan2
- DACT1 | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.123); catalogued as rs150721565, COSV60019320; called by muse, mutect2, varscan2
- DDC | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 27/275 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV63565682; called by muse, mutect2
- DDX17 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200653135; called by muse, mutect2, varscan2
- DDX3X | c.905G>T p.G302V (on ENST00000399959; = p.G303V on NM_001356.5) | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67863796; called by muse, mutect2
- DIP2A | c.2527G>T p.A843S | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV59477734; called by muse, mutect2, varscan2
- DKKL1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 95/380 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as rs774632178, COSV55562909; called by muse, mutect2, varscan2
- DNAH9 | c.3202C>T p.L1068F | Missense Mutation (SNP) | VAF 78/532 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs953638273; called by muse, mutect2, varscan2
- DOCK11 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52244351; called by mutect2, varscan2
- DPYSL4 | c.46C>A p.R16S | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs146177929; called by muse, mutect2, varscan2
- EDIL3 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1395379002; called by muse, mutect2, varscan2
- EFHC2 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.569); catalogued as COSV69553423; called by muse, mutect2
- ENDOV | c.56+1G>A p.X19_splice | Splice Site (SNP) | VAF 38/258 reads (15%) | catalogued as rs763342550; called by muse, mutect2, varscan2
- ENPP4 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781429930; called by muse, mutect2
- ERICH3 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs143871156; called by muse, mutect2, varscan2
- ESPNL | c.1751C>A p.P584H | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs1355066163; called by muse, mutect2, varscan2
- EVC2 | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.516); catalogued as rs761732269, COSV100185420; called by muse, mutect2, varscan2
- F5 | c.4123C>A p.L1375I | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs761713318; called by muse, mutect2, varscan2
- FAM120B | c.1834G>C p.D612H | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356948660; called by muse, mutect2, varscan2
- FAM47C | c.2725G>C p.V909L | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.31); catalogued as COSV63727022; called by muse, mutect2
- FAT3 | c.12836G>T p.G4279V | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53094163; called by muse, mutect2, varscan2
- FKBP6 | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 68/576 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV52721308; called by muse, mutect2, varscan2
- FTHL17 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV63266486; called by muse, mutect2, varscan2
- GABRA6 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761702862, COSV50883828, COSV99194556; called by muse, mutect2, varscan2
- GABRB1 | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54994190; called by muse, mutect2
- GALNT13 | c.856A>T p.R286W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV67235425; called by muse, mutect2, varscan2
- GFRAL | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV61235680; called by muse, mutect2
- GIGYF2 | c.3433G>C p.A1145P | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV101004429; called by muse, mutect2
- GIPR | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 84/652 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as COSV99624313; called by muse, varscan2
- GLT6D1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874528; called by muse, mutect2, varscan2
- GPKOW | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 30/655 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV50243275; called by muse, mutect2
- GPM6B | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57423467; called by muse, mutect2, varscan2
- GPR101 | c.436C>G p.R146G | Missense Mutation (SNP) | VAF 41/303 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as COSV99981475; called by muse, mutect2, varscan2
- GRAMD1B | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs780409933; called by muse, mutect2, varscan2
- HCRTR2 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV63794922, COSV63795120; called by muse, mutect2, varscan2
- HEPH | c.2221G>T p.E741* (on ENST00000343002; = p.E474* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/214 reads (8%) | catalogued as COSV57973624; called by muse, mutect2
- HIVEP1 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65098953, COSV65105568; called by muse, mutect2, varscan2
- HPN | c.618G>T p.P206= | Splice Region (SNP) | VAF 30/110 reads (27%) | catalogued as COSV52883738, COSV52885164; called by muse, mutect2, varscan2
- HRG | c.1279T>C p.C427R | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs776485907; called by muse, mutect2, varscan2
- HUS1B | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100032947, COSV57870288; called by muse, mutect2, varscan2
- IDI1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 136/418 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.062); catalogued as rs768280953; called by muse, mutect2, varscan2
- IFT27 | c.77G>A p.R26H (on ENST00000433985 / NM_001363003.2; = p.R25H on NM_006860.5) | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs185871181; called by muse, mutect2
- IGKV3D-11 | c.193A>G p.R65G | Missense Mutation (SNP) | VAF 80/729 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1244893670; called by muse, mutect2, varscan2
- IGKV5-2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1404049572; called by muse, mutect2, varscan2
- IL22RA1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs369268604; called by muse, mutect2, varscan2
- IL36B | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs781518301; called by muse, mutect2
- INF2 | c.1058T>A p.L353Q | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as rs1375713265; called by muse, mutect2, varscan2
- INSL4 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV53329834, COSV53329980; called by muse, mutect2, varscan2
- ITPR3 | c.1836G>C p.K612N | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.614); catalogued as rs1159683909; called by muse, mutect2, varscan2
- JHY | c.2228C>A p.A743D | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.308); catalogued as COSV57074920; called by muse, mutect2, varscan2
- KCNAB1 | c.1043C>T p.A348V (on ENST00000490337 / NM_172160.3; = p.A337V on NM_003471.3) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1465626441, COSV56754904; called by muse, mutect2, varscan2
- KIAA1549 | c.5675C>G p.S1892* (on ENST00000422774 / NM_001164665.2; = p.S1876* on NM_020910.3) | Nonsense Mutation (SNP) | VAF 38/151 reads (25%) | catalogued as COSV99650931; called by muse, varscan2
- LMX1A | c.989-1G>C p.X330_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as COSV54216424, COSV99672641; called by muse, mutect2, varscan2
- LRP1B | c.1974G>C p.W658C | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67192194; called by muse, mutect2, varscan2
- LRPAP1 | c.16G>T p.V6F | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs972906233; called by muse, mutect2
- MAP3K1 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 119/416 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761217931; called by muse, mutect2, varscan2
- MDGA1 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1187172146, COSV104396817; called by muse, mutect2, varscan2
- MEAK7 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs144320129, COSV100640391; called by muse, mutect2, varscan2
- MEIS1 | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV55486970; called by muse, mutect2
- MNDA | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs781216436; called by muse, mutect2, varscan2
- MUC16 | c.27256C>A p.P9086T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.281); catalogued as COSV67495725; called by muse, mutect2, varscan2
- MYADM | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV61238510, COSV61239936; called by muse, mutect2, varscan2
- MYO3A | c.2456G>C p.R819T | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV99780622; called by muse, mutect2, varscan2
- MYT1L | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67714431; called by muse, mutect2
- N6AMT1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs377369868; called by muse, mutect2
- NDUFA10 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1357362784; called by muse, varscan2
- NEXMIF | c.2335G>C p.A779P | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as COSV50071453; called by muse, mutect2
- NKX2-2 | c.525G>C p.W175C | Missense Mutation (SNP) | VAF 41/547 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65819461; called by muse, mutect2
- NLRC5 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52652420; called by muse, mutect2, varscan2
- NLRP3 | c.2198C>A p.S733* | Nonsense Mutation (SNP) | VAF 71/784 reads (9%) | catalogued as COSV60224348; called by muse, mutect2
- NMRK2 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.609); catalogued as COSV51455012; called by muse, mutect2, varscan2
- NOTCH4 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 153/465 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV66680693; called by muse, mutect2, varscan2
- OR2M7 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1197275256, COSV58741086; called by muse, mutect2, varscan2
- OR2T2 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 120/1451 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV100737836; called by muse, mutect2
- OR5B17 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs759198367; called by muse, mutect2
- OR5D14 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs778487794; called by muse, mutect2
- OR5F1 | c.421T>A p.Y141N | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53546406; called by muse, mutect2
- OR5T3 | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV57380398; called by muse, mutect2, varscan2
- OR8D1 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63442925; called by muse, mutect2
- PCDHB8 | c.1375C>A p.L459M | Missense Mutation (SNP) | VAF 177/665 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.777); catalogued as COSV50755900; called by muse, mutect2, varscan2
- PCLO | c.14348A>G p.K4783R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV61647013; called by muse, mutect2
- PIEZO2 | c.4443G>A p.M1481I | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57449571; called by muse, mutect2, varscan2
- PIK3C2B | c.4865G>C p.G1622A | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as COSV100916069; called by muse, mutect2, varscan2
- PLPPR5 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs770795047; called by muse, mutect2, varscan2
- PLXDC2 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as rs1016181126; called by muse, mutect2, varscan2
- PNPLA5 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546765786; called by muse, mutect2
- POLR3H | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531455869, COSV53445056; called by muse, varscan2
- PPFIA4 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as rs780105335; called by muse, mutect2, varscan2
- PPIP5K1 | c.3670G>A p.E1224K (on ENST00000396923; = p.E1199K on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs1370388915; called by muse, mutect2, varscan2
- PPP1R12B | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 47/534 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs766117310; called by muse, mutect2
- PRKCSH | c.271del p.R91Gfs*50 | Frame Shift Del (DEL) | VAF 76/665 reads (11%) | catalogued as COSV52954492; called by mutect2, pindel, varscan2
- PRSS48 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 100/480 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV71613906; called by muse, varscan2
- PSMA1 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV67166223; called by muse, mutect2, varscan2
- PTPN3 | c.1617G>C p.R539S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52702890; called by muse, mutect2, varscan2
- PTPRD | c.4912G>T p.G1638* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as COSV61948490; called by muse, mutect2, varscan2
- PTPRD | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); catalogued as COSV61929834; called by muse, mutect2, varscan2
- PTPRD | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.196); catalogued as COSV61972995; called by muse, mutect2, varscan2
- QRICH2 | c.2896A>C p.N966H | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs968542549; called by muse, mutect2, varscan2
- RAB3IP | c.527G>T p.R176L (on ENST00000550536 / NM_175623.4; = p.R160L on NM_022456.5) | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV56082842, COSV56085195; called by muse, mutect2, varscan2
- RAB9B | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54587354; called by muse, mutect2
- RBMXL2 | c.823A>T p.S275C | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1354970987; called by muse, mutect2, varscan2
- RBMXL3 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV57759992; called by muse, mutect2
- ROBO2 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100164581, COSV100169949; called by muse, mutect2, varscan2
- RP2 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV54463550; called by muse, mutect2
- RPTOR | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60818409; called by muse, mutect2, varscan2
- RTL3 | c.614C>A p.A205E | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1247660085; called by muse, mutect2, varscan2
- RTL5 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.225); catalogued as rs200189694; called by muse, mutect2
- RTL9 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV71826581; called by muse, mutect2
- RYR2 | c.13101G>C p.K4367N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV100769803; called by muse, mutect2
- SALL1 | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV51753393, COSV99175093; called by muse, varscan2
- SALL1 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV51764076, COSV51766047; called by muse, varscan2
- SEZ6L | c.1402A>G p.S468G | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.669); catalogued as rs753746720; called by muse, mutect2
- SH3PXD2B | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 147/504 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs1162266861; called by muse, mutect2, varscan2
- SH3RF2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 20/666 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100768035; called by muse, mutect2
- SIGLEC12 | c.1318G>T p.D440Y (on ENST00000291707 / NM_053003.4; = p.D322Y on NM_033329.2) | Missense Mutation (SNP) | VAF 85/395 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52465485; called by muse, mutect2, varscan2
- SIGLEC12 | c.576G>T p.K192N (on ENST00000291707 / NM_053003.4; = p.K74N on NM_033329.2) | Missense Mutation (SNP) | VAF 66/598 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99389669; called by muse, mutect2, varscan2
- SLC24A2 | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV53862527; called by muse, mutect2, varscan2
- SLC25A21 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as rs773529667; called by muse, mutect2, varscan2
- SLC5A11 | c.372+2T>A p.X124_splice | Splice Site (SNP) | VAF 58/209 reads (28%) | catalogued as rs1268088418, COSV100762771; called by muse, mutect2, varscan2
- SLC9A9 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57241472; called by muse, mutect2
- SLCO6A1 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV65812382; called by muse, mutect2, varscan2
- SORBS1 | c.3399G>T p.R1133S | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs375291668; called by muse, mutect2, varscan2
- SPANXB1 | c.39C>A p.S13R | Missense Mutation (SNP) | VAF 146/2744 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as rs1161024464; called by muse, mutect2
- SPCS1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs752641068, COSV51776974; called by muse, mutect2, varscan2
- SPTBN2 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 103/478 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.401); catalogued as rs1283630103; called by muse, mutect2, varscan2
- SV2A | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64964367; called by muse, mutect2, varscan2
- SVEP1 | c.7120C>T p.P2374S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836953; called by muse, mutect2
- TBC1D2 | c.2511G>C p.L837F (on ENST00000465784 / NM_001267571.2; = p.L826F on NM_018421.4) | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59787163; called by muse, mutect2, varscan2
- TBRG4 | c.1241G>T p.W414L | Missense Mutation (SNP) | VAF 99/530 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51831861; called by muse, mutect2, varscan2
- TCTEX1D4 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs964094612; called by muse, mutect2, varscan2
- TDP2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV57764631; called by muse, mutect2, varscan2
- TECPR1 | c.2619C>A p.D873E | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.136); catalogued as rs1458933405; called by muse, mutect2, varscan2
- TEKT5 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV51587556; called by muse, mutect2, varscan2
- TGM1 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 60/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM973208; called by muse, mutect2, varscan2
- THSD7B | c.3605C>A p.P1202H (on ENST00000272643; = p.P1200H on NM_001316349.2) | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55701590; called by muse, mutect2, varscan2
- TRERF1 | c.2772C>A p.C924* | Nonsense Mutation (SNP) | VAF 31/268 reads (12%) | catalogued as COSV100550667; called by muse, mutect2, varscan2
- TRPV4 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV55680112; called by muse, mutect2, varscan2
- TSHZ2 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 107/313 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100295559; called by muse, mutect2, varscan2
- TSKU | c.832C>A p.L278M | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60751769; called by muse, mutect2, varscan2
- TSPAN13 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771039340, COSV50437651; called by muse, mutect2
- TTC21A | c.363G>T p.W121C | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57183327; called by muse, mutect2, varscan2
- USH2A | c.3222G>T p.W1074C | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56330889; called by muse, mutect2, varscan2
- VAMP7 | c.501+1G>T p.X167_splice | Splice Site (SNP) | VAF 13/125 reads (10%) | catalogued as COSV52902039; called by muse, mutect2, varscan2
- VSIG10L2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as rs763018590; called by muse, mutect2, varscan2
- YTHDF1 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64833886; called by muse, mutect2, varscan2
- Z83844.2 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs759221673; called by muse, mutect2, varscan2
- ZBTB37 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV62933276; called by muse, mutect2, varscan2
- ZDHHC14 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as COSV58196069; called by muse, mutect2, varscan2
- ZNF17 | c.1733G>T p.R578M | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100300101; called by muse, mutect2, varscan2
- ZNF229 | c.2106C>A p.H702Q | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373616418; called by muse, mutect2, varscan2
- ZNF420 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58492518; called by muse, mutect2, varscan2
- ZNF566 | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs750951939, COSV101091285; called by muse, mutect2, varscan2
- ZNF600 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs1396038065; called by muse, mutect2, varscan2
- ZNF644 | c.3571C>G p.Q1191E | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs749519607; called by muse, mutect2, varscan2
- ZNF81 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV58484102; called by muse, mutect2
- A1CF | c.366-1G>C p.X122_splice | Splice Site (SNP) | VAF 10/57 reads (18%) | called by muse, varscan2
- ABCA13 | c.9883C>T p.Q3295* | Nonsense Mutation (SNP) | VAF 36/338 reads (11%) | called by muse, mutect2
- ABCC2 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 91/387 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADAMTS7 | c.4989G>T p.Q1663H | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS7 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADARB2 | c.362C>A p.S121* | Nonsense Mutation (SNP) | VAF 136/480 reads (28%) | called by muse, mutect2, varscan2
- ADCY1 | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ADCY5 | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ADGRG6 | c.3607del p.S1203Vfs*64 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- ADRB3 | c.755C>G p.P252R | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AKNAD1 | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- ALMS1 | c.5774G>A p.G1925E | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ALPK2 | c.3405G>T p.Q1135H | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALX1 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- ANHX | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ANKH | c.1306G>C p.G436R | Missense Mutation (SNP) | VAF 147/771 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD11 | c.7766C>G p.S2589C | Missense Mutation (SNP) | VAF 108/660 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD20A4P | c.1910C>T p.T637I | Missense Mutation (SNP) | VAF 89/551 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ANLN | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- AOC1 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- APMAP | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.406); called by muse, mutect2
- ARHGEF37 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ARID5B | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- ARMC3 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASB7 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- ASXL2 | c.3809A>G p.Q1270R | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- ATP2B3 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- ATP4A | c.689C>G p.T230R | Missense Mutation (SNP) | VAF 54/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AXIN2 | c.1699A>T p.S567C | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- B3GAT3 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 79/399 reads (20%) | called by muse, mutect2, varscan2
- BCAS3 | c.139-1G>A p.X47_splice | Splice Site (SNP) | VAF 11/101 reads (11%) | called by muse, varscan2
- BCHE | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- C10orf53 | c.98-2A>G p.X33_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- C1orf53 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 117/592 reads (20%) | called by muse, mutect2, varscan2
- CABP1 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CACNB2 | c.1199C>T p.S400F (on ENST00000324631 / NM_201596.3; = p.S345F on NM_000724.4) | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CADM2 | c.946G>T p.V316F (on ENST00000407528 / NM_001167674.2; = p.V318F on NM_153184.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAPSL | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- CCDC18 | c.2683G>C p.E895Q (on ENST00000343253 / NM_001306076.1; = p.E896Q on NM_206886.4) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CD2 | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 54/604 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CD5L | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CDC20B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDCP2 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 37/440 reads (8%) | called by muse, mutect2
- CDH18 | c.95A>T p.K32M | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); called by muse, mutect2
- CELSR2 | c.4439C>T p.A1480V | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.429); called by muse, mutect2
- CERKL | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP46 | c.4821A>C p.E1607D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHEK1 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CHRM2 | c.1111C>A p.Q371K | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CIC | c.3844G>C p.G1282R | Missense Mutation (SNP) | VAF 57/494 reads (12%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CLASP1 | c.4606A>T p.T1536S | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCA4 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | called by muse, varscan2
- CLDN17 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLNK | c.12-3C>A | Splice Region (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- CMTR2 | c.861_872del p.M288_L291del | In Frame Del (DEL) | VAF 24/104 reads (23%) | called by mutect2, pindel, varscan2
- CMYA5 | c.3241C>G p.P1081A | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- COL12A1 | c.8260C>T p.P2754S | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL19A1 | c.2468A>T p.N823I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, varscan2
- COL4A5 | c.4900G>T p.G1634W | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A5 | c.4901G>T p.G1634V | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COPS7B | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 45/413 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CORIN | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COX18 | c.769A>T p.T257S | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2
- CPS1 | c.3946C>G p.P1316A | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- CRACD | c.2519A>G p.E840G | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, varscan2
- CSF3 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYP2B6 | c.705del p.Y235* | Frame Shift Del (DEL) | VAF 114/448 reads (25%) | called by mutect2, varscan2
- CYP4F22 | c.1419G>A p.R473= | Splice Region (SNP) | VAF 47/419 reads (11%) | called by muse, mutect2, varscan2
- DCC | c.1347G>C p.W449C | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCHS1 | c.5371G>T p.D1791Y | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DDX5 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- DMD | c.1723C>A p.L575I | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- DNAH1 | c.2764G>T p.G922W | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH1 | c.9415A>T p.N3139Y | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH5 | c.3581C>A p.S1194Y | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DPPA2 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- DQX1 | c.690G>C p.E230D | Missense Mutation (SNP) | VAF 13/239 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.024); called by muse, mutect2
- DZANK1 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- EDA | c.899C>A p.T300N | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EFHD1 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENDOV | c.56+2T>A p.X19_splice | Splice Site (SNP) | VAF 37/252 reads (15%) | called by muse, mutect2, varscan2
- ERCC3 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 41/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESRRG | c.718C>A p.H240N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ETFDH | c.837G>A p.W279* | Nonsense Mutation (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- EYS | c.6665T>C p.I2222T | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM102A | c.857G>T p.R286L (on ENST00000373095 / NM_001035254.3; = p.R144L on NM_203305.2) | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.096); called by muse, varscan2
- FAM166C | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2
- FAT4 | c.3634A>G p.K1212E | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FBLIM1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXL15 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 75/546 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FCN1 | c.140T>A p.L47H | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FCRL3 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FHL1 | c.397A>T p.K133* | Nonsense Mutation (SNP) | VAF 45/514 reads (9%) | called by muse, mutect2
- FLI1 | c.1188G>T p.Q396H | Missense Mutation (SNP) | VAF 93/653 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FLT1 | c.3349A>G p.M1117V | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FMN2 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- G6PC | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 80/646 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GANAB | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GDA | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- GMCL2 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GNAT3 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPATCH11 | c.407T>G p.I136S (on ENST00000409774; = p.I114S on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- GPM6B | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 25/415 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2
- GPR12 | c.235A>T p.M79L | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- GPR141 | c.497G>C p.C166S | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR63 | c.653C>G p.P218R | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GPRASP1 | c.3586G>A p.G1196S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK3 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRXCR1 | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSTM2 | c.616A>T p.R206* | Nonsense Mutation (SNP) | VAF 85/696 reads (12%) | called by muse, mutect2, varscan2
- H3-5 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- HCN4 | c.2959G>T p.A987S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HCRTR1 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- HDAC8 | c.910+3G>A | Splice Region (SNP) | VAF 24/239 reads (10%) | called by muse, mutect2, varscan2
- HECW2 | c.1405G>C p.D469H | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HEPH | c.1614G>C p.M538I (on ENST00000343002; = p.M271I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2
- HIC2 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- HIVEP2 | c.3772G>T p.E1258* | Nonsense Mutation (SNP) | VAF 55/301 reads (18%) | called by muse, mutect2, varscan2
- HMGB2 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HOXD3 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HRH1 | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HRH2 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- HTR1A | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUNK | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 28/284 reads (10%) | called by muse, mutect2, varscan2
- HYDIN | c.8251G>T p.E2751* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- IGBP1 | c.413C>A p.T138N | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.309); called by muse, mutect2
- IGHV1OR15-9 | c.49dup p.A17Gfs*13 | Frame Shift Ins (INS) | VAF 63/252 reads (25%) | called by mutect2, pindel, varscan2
- IGSF9B | c.4077G>T p.K1359N | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL10RB | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- IL6ST | c.2540G>A p.R847K | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- IL9R | c.611T>A p.V204E | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- IMPG1 | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INPP4A | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSYN2B | c.231del p.T78Pfs*74 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- IRAG2 | c.4141T>A p.W1381R (on ENST00000636465; = p.W426R on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA4 | c.448A>C p.N150H | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA8 | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH1 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 91/687 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IZUMO3 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- JAK3 | c.1567T>A p.W523R | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- JAK3 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 34/437 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- KCNH8 | c.1292G>C p.S431T | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KIF21B | c.1665G>T p.E555D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- KLHL1 | c.1198T>A p.F400I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KRTAP5-5 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 52/498 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- L3MBTL4 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- LAMC3 | c.3620T>A p.L1207Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- LAMP2 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- LAMTOR4 | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- LEFTY2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 106/505 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR5 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LIPI | c.466A>T p.S156C | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.831); called by muse, mutect2
- LMAN1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LNX2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LPO | c.89G>T p.R30I | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- LRIT2 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LRRC1 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.3602C>A p.S1201Y (on ENST00000651989 / NM_001370785.2; = p.S1168Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRRK1 | c.3049G>T p.V1017L | Missense Mutation (SNP) | VAF 86/410 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK2 | c.3812C>T p.T1271I | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRK2 | c.4178G>T p.W1393L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LTBP1 | c.2119G>T p.G707C (on ENST00000404816 / NM_206943.4; = p.G381C on NM_000627.4) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUM | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAB21L1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2, varscan2
- MALRD1 | c.5573C>T p.S1858F | Missense Mutation (SNP) | VAF 50/497 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK3 | c.774G>T p.L258= | Splice Region (SNP) | VAF 59/189 reads (31%) | called by muse, mutect2, varscan2
- MAPT | c.2387C>T p.S796F (on ENST00000262410 / NM_001377265.1; = p.S404F on NM_005910.5) | Missense Mutation (SNP) | VAF 81/757 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED18 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MEGF11 | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 71/289 reads (25%) | called by muse, mutect2, varscan2
- MGAM2 | c.2166T>A p.G722= | Splice Region (SNP) | VAF 34/187 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.3807G>T p.M1269I | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5AC | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYCBP2 | c.12745A>T p.R4249* (on ENST00000357337; = p.R4287* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- MYO18B | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MYOF | c.5825A>C p.E1942A | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYT1L | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- N4BP1 | c.2225+1G>T p.X742_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- NAALADL2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- NBAS | c.4933G>T p.A1645S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEK1 | c.3730C>T p.H1244Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NELL2 | c.861G>T p.W287C | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NETO1 | c.1223C>A p.A408E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NFYC | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- NPB | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- NRDE2 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP42 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OLFML2B | c.30C>G p.Y10* | Nonsense Mutation (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- OPLAH | c.2735del p.G912Efs*93 | Frame Shift Del (DEL) | VAF 55/177 reads (31%) | called by mutect2, pindel, varscan2
- OPN1SW | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, varscan2
- OR10A3 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10J3 | c.178A>T p.M60L | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- OR14I1 | c.334T>G p.F112V | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, varscan2
- OR1C1 | c.885G>T p.R295S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- OR1C1 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR2A2 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR52J3 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- OR56A3 | c.549T>A p.C183* | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- OR9A2 | c.300C>G p.N100K | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- OTOG | c.7564G>T p.G2522C | Missense Mutation (SNP) | VAF 80/323 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OTOG | c.8267G>T p.C2756F | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- PAK1IP1 | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- PCDHA9 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PHEX | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- PIEZO2 | c.4444G>A p.D1482N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PIGN | c.2176A>G p.T726A | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PIP5K1B | c.845del p.E282Gfs*40 | Frame Shift Del (DEL) | VAF 39/279 reads (14%) | called by mutect2, pindel, varscan2
- PIR | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7231G>C p.D2411H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, varscan2
- PLCXD3 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- PLOD1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 50/370 reads (14%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4180C>A p.L1394M | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA4 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 93/462 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- POTEB3 | c.1055+1G>T p.X352_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | called by mutect2, varscan2
- PPIL6 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PPP4R3C | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2
- PRAMEF14 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PRDM10 | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PRRT4 | c.2397C>A p.S799R | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PTGS1 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRB | c.5215+1G>T p.X1739_splice | Splice Site (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- PTPRB | c.4285T>A p.S1429T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRD | c.5449G>T p.G1817* | Nonsense Mutation (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- PXDNL | c.2996A>G p.Q999R | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- QARS1 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 58/393 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RAB12 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RAB41 | c.180C>A p.C60* (on ENST00000374473 / NM_001363807.1; = p.C59* on NM_001032726.3) | Nonsense Mutation (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- RAI1 | c.5630C>T p.T1877I | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- RASGEF1B | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- RBM19 | c.1132A>G p.K378E | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RELN | c.8708C>G p.P2903R | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RESF1 | c.1234A>G p.R412G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RFX6 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS3 | c.2601G>T p.Q867H (on ENST00000350696 / NM_001282923.2; = p.Q586H on NM_130795.4) | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGSL1 | c.122C>G p.T41S | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RHBDF2 | c.2490G>T p.W830C | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS1 | c.3182G>T p.W1061L | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.321); called by muse, mutect2
- ROCK2 | c.3664A>G p.K1222E | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ROR2 | c.694T>C p.C232R | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPA3 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- RPH3AL | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- RRAGD | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- RRNAD1 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, varscan2
- RUNDC3B | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RYR2 | c.3952G>A p.V1318M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RYR2 | c.5469G>T p.K1823N | Missense Mutation (SNP) | VAF 116/576 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, varscan2
- SAGE1 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- SALL3 | c.1651C>A p.R551S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.325); called by muse, mutect2
- SEMA6C | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 125/561 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SETBP1 | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SEZ6L | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEZ6L | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SH3RF1 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHANK1 | c.5902G>T p.A1968S | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SIDT2 | c.2453A>G p.D818G | Missense Mutation (SNP) | VAF 20/565 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SKOR2 | c.1269G>C p.K423N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- SLC13A5 | c.1406C>A p.T469N | Missense Mutation (SNP) | VAF 113/438 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SLC22A12 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 60/628 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SLC25A45 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SLC27A6 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SLC2A14 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLC3A2 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 111/468 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SLC6A8 | c.1609T>A p.F537I | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- SNCAIP | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SOHLH2 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORCS1 | c.3360C>A p.Y1120* | Nonsense Mutation (SNP) | VAF 43/354 reads (12%) | called by muse, mutect2, varscan2
- SPEG | c.3492-1G>T p.X1164_splice | Splice Site (SNP) | VAF 35/128 reads (27%) | called by muse, mutect2, varscan2
- SPIN1 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SPTA1 | c.3925G>T p.G1309C | Missense Mutation (SNP) | VAF 90/462 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SPTBN5 | c.9449T>A p.F3150Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SRRT | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 94/564 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ST6GAL2 | c.843del p.A282Pfs*4 | Frame Shift Del (DEL) | VAF 20/154 reads (13%) | called by mutect2, pindel, varscan2
- STAMBP | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- STAR | c.179-4C>A | Splice Region (SNP) | VAF 52/449 reads (12%) | called by muse, mutect2, varscan2
- STRC | c.4425del p.W1475Cfs*18 | Frame Shift Del (DEL) | VAF 92/470 reads (20%) | called by mutect2, pindel, varscan2
- SULT1E1 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 13/237 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.254); called by muse, mutect2
- SUPT20HL1 | c.1876A>G p.S626G | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVIL | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SVIL | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SYNE2 | c.16172G>T p.S5391I | Missense Mutation (SNP) | VAF 98/525 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SZT2 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- TACC2 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- TARBP1 | c.2772G>T p.M924I | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TAS1R3 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCEAL6 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 35/345 reads (10%) | called by muse, mutect2, varscan2
- TEK | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENM1 | c.3095G>C p.R1032P | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TESMIN | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TFAP2D | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TGM6 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 60/441 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TIPARP | c.1837A>T p.S613C | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TJP2 | c.3322-3C>G | Splice Region (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- TLL1 | c.2596G>T p.V866F | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- TMEM131 | c.4994G>T p.G1665V | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM161A | c.676G>C p.A226P | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); called by muse, mutect2
- TMEM178B | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- TMEM19 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- TMEM67 | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- TMPRSS11D | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC11 | c.1574C>G p.T525S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIM46 | c.801C>A p.Y267* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- TRIM58 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPM2 | c.1345C>A p.H449N | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TSPAN7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/270 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, varscan2
- TTN | c.74671G>C p.E24891Q (on ENST00000591111; = p.E17467Q on NM_003319.4) | Missense Mutation (SNP) | VAF 30/354 reads (8%) | PolyPhen possibly damaging (0.603); called by muse, mutect2
- TTN | c.35404C>T p.P11802S (on ENST00000591111; = p.P10875S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/257 reads (5%) | PolyPhen possibly damaging (0.587); called by muse, mutect2
- TTN | c.33346G>A p.E11116K (on ENST00000591111; = p.E10189K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TTN | c.18887A>T p.E6296V (on ENST00000591111; = p.E5369V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/146 reads (17%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTYH2 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- UNC13B | c.4666G>A p.E1556K | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- UNC5B | c.2672G>C p.R891P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.9318G>T p.Q3106H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- UPF1 | c.3186G>T p.Q1062H (on ENST00000599848 / NM_001297549.2; = p.Q1051H on NM_002911.4) | Missense Mutation (SNP) | VAF 159/643 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UPF1 | c.3187G>T p.G1063C (on ENST00000599848 / NM_001297549.2; = p.G1052C on NM_002911.4) | Missense Mutation (SNP) | VAF 158/640 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- USH2A | c.9389G>T p.W3130L | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, varscan2
- USH2A | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USHBP1 | c.1020dup p.A341Sfs*10 | Frame Shift Ins (INS) | VAF 26/139 reads (19%) | called by mutect2, pindel, varscan2
- USP28 | c.2810del p.R937Pfs*8 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, varscan2
- USP41 | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- VNN2 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VNN2 | c.992C>A p.P331Q | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- VPS41 | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2
- VPS51 | c.359-1G>T p.X120_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- VRTN | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- VSTM2A | c.102del p.N35Tfs*2 | Frame Shift Del (DEL) | VAF 70/606 reads (12%) | called by mutect2, varscan2
- VWF | c.3766A>G p.T1256A | Missense Mutation (SNP) | VAF 135/464 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- WDR36 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- YTHDF1 | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ZBED9 | c.1724G>T p.S575I | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.806); called by muse, mutect2
- ZFPM2 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 42/413 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZIC2 | c.954C>G p.Y318* | Nonsense Mutation (SNP) | VAF 24/548 reads (4%) | called by muse, mutect2
- ZIC4 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ZNF185 | c.833G>C p.R278T | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- ZNF282 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ZNF283 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ZNF461 | c.1246C>A p.H416N | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF490 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ZNF716 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ZNF804B | c.2219T>A p.L740H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- AATK | c.69C>G p.L23= | Silent (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2, varscan2
- AC231657.3 | c.567G>T p.A189= | Silent (SNP) | VAF 50/723 reads (7%) | called by muse, mutect2
- ACTN2 | c.2445C>T p.I815= | Silent (SNP) | VAF 92/640 reads (14%) | catalogued as rs397516575, COSV63974599; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADCY1 | c.2472G>A p.E824= | Silent (SNP) | VAF 62/306 reads (20%) | catalogued as COSV52029471; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1404C>A p.T468= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs1402193505; called by muse, mutect2, varscan2
- AKAP4 | c.1212C>A p.V404= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- ALMS1 | c.12201G>A p.K4067= | Silent (SNP) | VAF 118/538 reads (22%) | called by muse, mutect2, varscan2
- ARPC2 | c.603C>T p.S201= | Silent (SNP) | VAF 33/288 reads (11%) | called by muse, mutect2, varscan2
- ARSK | c.333A>T p.T111= | Silent (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- AUTS2 | c.369G>A p.K123= | Silent (SNP) | VAF 31/280 reads (11%) | catalogued as COSV100718182, COSV61433411; called by muse, mutect2, varscan2
- B3GAT3 | c.438G>T p.R146= | Silent (SNP) | VAF 78/394 reads (20%) | called by muse, mutect2, varscan2
- BICC1 | c.312C>A p.P104= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- BNIP5 | c.225C>G p.A75= | Silent (SNP) | VAF 47/442 reads (11%) | called by muse, mutect2, varscan2
- CDCP2 | c.192G>A p.E64= | Silent (SNP) | VAF 36/444 reads (8%) | catalogued as rs1217904687; called by muse, mutect2
- CDH10 | c.477G>A p.T159= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as rs559592064, COSV52580188; called by muse, mutect2, varscan2
- CEACAM20 | c.1758C>T p.P586= | Silent (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- CLCNKB | c.1368G>T p.G456= | Silent (SNP) | VAF 79/479 reads (16%) | called by muse, mutect2, varscan2
- COPS7B | c.705G>A p.L235= | Silent (SNP) | VAF 45/412 reads (11%) | catalogued as rs1402574931; called by muse, mutect2, varscan2
- CUL1 | c.1488C>T p.C496= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs750560055, COSV100296575; called by muse, mutect2, varscan2
- DCX | c.1054C>T p.L352= (on ENST00000636035 / NM_001195553.2; = p.L346= on NM_000555.3) | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- DDR2 | c.2154G>T p.V718= | Silent (SNP) | VAF 68/376 reads (18%) | catalogued as COSV100906731, COSV63368941; called by muse, mutect2, varscan2
- DNAH9 | c.7659T>C p.D2553= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as rs772211329; called by muse, mutect2, varscan2
- DOCK9 | c.5841C>T p.I1947= (on ENST00000376460 / NM_001366676.2; = p.I1948= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/451 reads (9%) | catalogued as rs775822351; called by muse, mutect2
- DPF3 | c.399C>A p.A133= | Silent (SNP) | VAF 54/357 reads (15%) | called by muse, mutect2, varscan2
- EDNRA | c.996G>T p.V332= | Silent (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.3232C>A p.R1078= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- FADS3 | c.28C>A p.R10= | Silent (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- FCRL5 | c.2328G>C p.L776= | Silent (SNP) | VAF 24/444 reads (5%) | catalogued as COSV62512484, COSV62518894; called by muse, mutect2
- GPR87 | c.762C>A p.I254= | Silent (SNP) | VAF 55/244 reads (23%) | called by muse, mutect2, varscan2
- GREB1L | c.4507C>A p.R1503= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs561529182, COSV52551588; called by muse, mutect2, varscan2
- HCN1 | c.120C>A p.G40= | Silent (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- HCRTR1 | c.495C>A p.I165= | Silent (SNP) | VAF 78/510 reads (15%) | called by muse, varscan2
- HIP1 | c.249G>T p.L83= | Silent (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- HIVEP3 | c.2844G>C p.S948= | Silent (SNP) | VAF 36/373 reads (10%) | called by muse, mutect2
- HOXB5 | c.198T>C p.F66= | Silent (SNP) | VAF 30/114 reads (26%) | called by muse, varscan2
- HS3ST1 | c.75A>T p.L25= | Silent (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- HTR2A | c.711C>A p.I237= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as COSV66328037; called by muse, mutect2, varscan2
- HUNK | c.1899G>A p.E633= | Silent (SNP) | VAF 30/287 reads (10%) | called by muse, mutect2, varscan2
- IBSP | c.741T>C p.T247= | Silent (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.15C>A p.V5= | Silent (SNP) | VAF 36/303 reads (12%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.306T>A p.P102= | Silent (SNP) | VAF 49/365 reads (13%) | called by muse, mutect2, varscan2
- INTS5 | c.2553C>T p.F851= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV57951537; called by muse, mutect2
- INTS5 | c.2340C>T p.L780= | Silent (SNP) | VAF 35/342 reads (10%) | catalogued as COSV57950118; called by muse, mutect2
- ITGA6 | c.372A>T p.P124= | Silent (SNP) | VAF 55/535 reads (10%) | called by muse, mutect2, varscan2
- JAG1 | c.378C>T p.F126= | Silent (SNP) | VAF 35/692 reads (5%) | catalogued as CD030141, COSV99653394; called by muse, mutect2
- JAK3 | c.816C>A p.R272= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- KANK4 | c.2094G>A p.K698= | Silent (SNP) | VAF 27/197 reads (14%) | catalogued as rs1248223968; called by muse, mutect2, varscan2
- KCNH1 | c.1410C>A p.A470= (on ENST00000271751 / NM_172362.3; = p.A443= on NM_002238.4) | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- KCNH4 | c.837C>A p.I279= | Silent (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- KCNK3 | c.354C>T p.I118= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1390180986, COSV57194935; called by muse, mutect2, varscan2
- KIR3DL2 | c.738C>T p.S246= | Silent (SNP) | VAF 46/343 reads (13%) | called by muse, mutect2, varscan2
- KRTAP2-4 | c.243C>A p.P81= | Silent (SNP) | VAF 25/392 reads (6%) | called by muse, mutect2
- LGI4 | c.588C>T p.L196= | Silent (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- LILRA2 | c.1377C>A p.V459= (on ENST00000391738 / NM_001130917.3; = p.V442= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/272 reads (26%) | catalogued as COSV52196746, COSV99253778; called by muse, mutect2, varscan2
- LILRB2 | c.463C>T p.L155= | Silent (SNP) | VAF 39/480 reads (8%) | catalogued as COSV58748221; called by muse, mutect2
- LIN7A | c.21T>C p.T7= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- LPA | c.4206C>A p.T1402= | Silent (SNP) | VAF 39/288 reads (14%) | catalogued as rs751717117; called by muse, mutect2, varscan2
- MAGED1 | c.1164C>G p.T388= | Silent (SNP) | VAF 32/440 reads (7%) | called by muse, mutect2
- MASP1 | c.621C>T p.P207= | Silent (SNP) | VAF 29/229 reads (13%) | called by muse, mutect2, varscan2
- MDC1 | c.4779A>G p.T1593= | Silent (SNP) | VAF 46/472 reads (10%) | catalogued as rs371686223; called by muse, mutect2, varscan2
- MPP7 | c.420C>T p.I140= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as rs267602464, COSV61731856; called by muse, mutect2, varscan2
- MUC5AC | c.13635C>T p.L4545= | Silent (SNP) | VAF 74/538 reads (14%) | catalogued as rs779120044; called by muse, varscan2
- MXRA5 | c.4365A>T p.A1455= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- MYBL1 | c.1452A>T p.L484= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- MYH8 | c.1170C>A p.L390= | Silent (SNP) | VAF 47/357 reads (13%) | called by muse, mutect2, varscan2
- MYO16 | c.1377C>T p.F459= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- MYO7A | c.3816G>T p.L1272= | Silent (SNP) | VAF 38/263 reads (14%) | called by muse, mutect2, varscan2
- NAA16 | c.615G>T p.L205= | Silent (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2
- NCAM1 | c.2295C>G p.P765= (on ENST00000316851 / NM_181351.5; = p.P755= on NM_000615.7) | Silent (SNP) | VAF 58/412 reads (14%) | catalogued as COSV100377303; called by muse, mutect2, varscan2
- NDUFA10 | c.12G>T p.R4= | Silent (SNP) | VAF 42/414 reads (10%) | called by muse, varscan2
- NECAB2 | c.822C>A p.R274= | Silent (SNP) | VAF 115/473 reads (24%) | catalogued as COSV59420291; called by muse, mutect2, varscan2
- NEPRO | c.18G>T p.P6= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as rs747603041; called by muse, mutect2, varscan2
- NGFR | c.1065G>T p.A355= | Silent (SNP) | VAF 25/255 reads (10%) | called by muse, mutect2, varscan2
- NOL11 | c.1659A>G p.E553= | Silent (SNP) | VAF 37/197 reads (19%) | called by muse, mutect2, varscan2
- NONO | c.1164T>A p.A388= | Silent (SNP) | VAF 19/354 reads (5%) | called by muse, mutect2
- NOX3 | c.1059C>A p.I353= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- NXPE4 | c.1434G>A p.R478= (on ENST00000375478 / NM_001077639.2; = p.R194= on NM_017678.3) | Silent (SNP) | VAF 51/243 reads (21%) | called by muse, mutect2, varscan2
- NYNRIN | c.3511C>T p.L1171= | Silent (SNP) | VAF 100/350 reads (29%) | called by muse, mutect2, varscan2
- OR10AG1 | c.759C>G p.P253= | Silent (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- OR10J3 | c.177C>A p.P59= | Silent (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- OR51B5 | c.669C>T p.V223= | Silent (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- OR51E1 | c.354G>T p.L118= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- P4HB | c.105G>C p.A35= | Silent (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2, varscan2
- PAX3 | c.1395C>T p.G465= | Silent (SNP) | VAF 25/292 reads (9%) | called by muse, mutect2
- PCDH17 | c.795G>A p.L265= | Silent (SNP) | VAF 40/345 reads (12%) | catalogued as COSV64972223; called by muse, mutect2, varscan2
- PCDHB14 | c.1104T>C p.F368= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- PCDHB4 | c.2226G>C p.G742= | Silent (SNP) | VAF 119/510 reads (23%) | catalogued as COSV52023355; called by muse, mutect2, varscan2
- PCDHGA3 | c.1120C>A p.R374= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs775928851, COSV53923684; called by muse, mutect2, varscan2
- PCSK9 | c.849G>T p.L283= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- PDE1C | c.2121C>T p.N707= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- PIGZ | c.312C>T p.F104= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2
- PKHD1 | c.2784G>A p.G928= | Silent (SNP) | VAF 39/423 reads (9%) | called by muse, mutect2
- PLEKHA6 | c.2479C>A p.R827= | Silent (SNP) | VAF 39/389 reads (10%) | called by muse, mutect2, varscan2
- POLK | c.723G>C p.L241= | Silent (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- PPARA | c.24C>G p.L8= | Silent (SNP) | VAF 52/355 reads (15%) | catalogued as rs752011597; called by muse, mutect2, varscan2
- PPRC1 | c.1329G>A p.Q443= | Silent (SNP) | VAF 28/244 reads (11%) | called by muse, mutect2, varscan2
- PRDM9 | c.1098C>A p.G366= | Silent (SNP) | VAF 77/426 reads (18%) | called by muse, mutect2, varscan2
- PROSER2 | c.1191C>G p.R397= | Silent (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
- PRSS48 | c.864C>G p.L288= | Silent (SNP) | VAF 36/366 reads (10%) | called by muse, mutect2
- PTPRB | c.4284G>A p.Q1428= | Silent (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- PTPRD | c.3687G>A p.V1229= | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- QARS1 | c.654G>T p.L218= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs1291792145; called by muse, mutect2, varscan2
- RAB39B | c.195C>T p.T65= | Silent (SNP) | VAF 40/378 reads (11%) | catalogued as COSV65625413; called by muse, mutect2
- RANBP2 | c.6222G>A p.L2074= | Silent (SNP) | VAF 80/701 reads (11%) | called by muse, mutect2, varscan2
- RAX | c.474C>T p.S158= | Silent (SNP) | VAF 45/338 reads (13%) | catalogued as rs1568097710; called by muse, mutect2, varscan2
- RBM46 | c.789A>T p.A263= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- RBP3 | c.1590C>G p.R530= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- RERE | c.4224G>T p.S1408= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- RGSL1 | c.390C>T p.S130= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV54254966; called by muse, mutect2, varscan2
- RGSL1 | c.663C>T p.S221= | Silent (SNP) | VAF 23/182 reads (13%) | catalogued as rs771253084; called by muse, mutect2, varscan2
- RNF213 | c.3339G>A p.K1113= | Silent (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- RPS14 | c.438C>T p.R146= | Silent (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- RRBP1 | c.93C>T p.F31= | Silent (SNP) | VAF 36/522 reads (7%) | catalogued as rs906212949; called by muse, mutect2
- RTN1 | c.2049G>A p.V683= | Silent (SNP) | VAF 39/221 reads (18%) | called by muse, mutect2, varscan2
- RUNDC1 | c.567C>G p.L189= | Silent (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- RUNX3 | c.261G>A p.K87= | Silent (SNP) | VAF 52/342 reads (15%) | called by muse, varscan2
- SEZ6L | c.2967C>G p.R989= | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- SGSM2 | c.165G>C p.L55= | Silent (SNP) | VAF 77/574 reads (13%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1281C>A p.S427= | Silent (SNP) | VAF 42/379 reads (11%) | called by muse, mutect2, varscan2
- SLC26A9 | c.312C>A p.L104= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV61604976; called by muse, mutect2, varscan2
- SLC30A8 | c.951T>A p.A317= | Silent (SNP) | VAF 22/227 reads (10%) | called by muse, mutect2
- SLC40A1 | c.690C>A p.T230= | Silent (SNP) | VAF 36/276 reads (13%) | called by muse, mutect2, varscan2
- SLC4A1 | c.2595C>T p.L865= | Silent (SNP) | VAF 63/538 reads (12%) | called by muse, mutect2, varscan2
- SLC4A2 | c.789G>A p.Q263= | Silent (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- SLC8A1 | c.2400C>T p.G800= | Silent (SNP) | VAF 80/338 reads (24%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.1135C>T p.L379= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs1434373181; called by muse, varscan2
- SLITRK1 | c.1668C>A p.L556= | Silent (SNP) | VAF 44/603 reads (7%) | called by muse, mutect2
- SP8 | c.468C>A p.S156= (on ENST00000361443 / NM_198956.4; = p.S174= on NM_182700.6) | Silent (SNP) | VAF 44/240 reads (18%) | called by muse, varscan2
- SSTR4 | c.444G>T p.V148= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- STEAP2 | c.1452G>A p.P484= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs201134508, COSV55288941; called by muse, mutect2, varscan2
- STK26 | c.1170C>T p.A390= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs374158091; called by muse, mutect2, varscan2
- TAS2R38 | c.219G>A p.L73= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- TCHHL1 | c.2127G>A p.E709= | Silent (SNP) | VAF 36/253 reads (14%) | called by muse, mutect2, varscan2
- TMEM131 | c.2361G>T p.L787= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- TRIM42 | c.355C>T p.L119= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- TSPEAR | c.1602C>A p.I534= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs201961551; called by muse, mutect2, varscan2
- TTN | c.85026G>A p.V28342= (on ENST00000591111; = p.V20918= on NM_003319.4) | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs1281525934; called by muse, mutect2
- TTN | c.82008T>C p.Y27336= (on ENST00000591111; = p.Y19912= on NM_003319.4) | Silent (SNP) | VAF 50/518 reads (10%) | catalogued as rs769100292; called by muse, mutect2
- TXLNB | c.1362C>A p.L454= | Silent (SNP) | VAF 71/518 reads (14%) | catalogued as rs773301481; called by muse, mutect2, varscan2
- UBQLN3 | c.1248C>A p.P416= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2
- UNC13A | c.4938C>A p.R1646= | Silent (SNP) | VAF 59/416 reads (14%) | catalogued as rs1163946146; called by muse, mutect2, varscan2
- UNC93A | c.162C>T p.S54= | Silent (SNP) | VAF 39/331 reads (12%) | catalogued as COSV100023297; called by muse, mutect2, varscan2
- URGCP | c.2514C>G p.L838= (on ENST00000453200 / NM_001077663.3; = p.L829= on NM_017920.4) | Silent (SNP) | VAF 65/566 reads (11%) | catalogued as COSV99786931; called by muse, mutect2, varscan2
- VCAM1 | c.1869T>C p.C623= | Silent (SNP) | VAF 40/252 reads (16%) | called by muse, mutect2, varscan2
- VNN1 | c.165G>T p.R55= | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as COSV100907799; called by muse, mutect2, varscan2
- VPS51 | c.561C>T p.L187= | Silent (SNP) | VAF 49/432 reads (11%) | called by muse, mutect2, varscan2
- VRTN | c.315G>T p.R105= | Silent (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- ZDBF2 | c.5283T>C p.D1761= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- ZNF335 | c.2586C>G p.G862= | Silent (SNP) | VAF 202/603 reads (33%) | catalogued as COSV100533171; called by mutect2, varscan2
- ZNF423 | c.2610G>T p.L870= (on ENST00000563137 / NM_001379286.1; = p.L862= on NM_015069.4) | Silent (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- ZNF441 | c.474A>T p.I158= | Silent (SNP) | VAF 69/223 reads (31%) | called by muse, mutect2, varscan2
- ZNF711 | c.435C>A p.V145= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- ZNF804B | c.2136G>A p.L712= | Silent (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- AC100872.1 | chr8:122670526 G>A | 5'Flank (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- ACSF3 | c.*1339G>T | 3'UTR (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- ACTN2 | c.784-464C>T | Intron (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- ADGRD1 | c.966+1805C>G | Intron (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- AGAP3 | c.224-1944G>A | Intron (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822371 C>A | 5'Flank (SNP) | VAF 82/381 reads (22%) | called by muse, mutect2, varscan2
- AMPH | c.1272+1430C>G | Intron (SNP) | VAF 22/201 reads (11%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*640C>G | 3'UTR (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- ANKS6 | c.*4016C>T | 3'UTR (SNP) | VAF 41/416 reads (10%) | called by muse, mutect2
- ATG16L2 | c.644+65C>G | Intron (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- AUP1 | c.339+64del | Intron (DEL) | VAF 16/170 reads (9%) | catalogued as COSV51212754; called by mutect2, pindel
- BIN1 | c.1240-20G>T | Intron (SNP) | VAF 119/580 reads (21%) | called by muse, mutect2, varscan2
- BTNL10 | n.344G>C | RNA (SNP) | VAF 12/383 reads (3%) | called by muse, mutect2
- C22orf15 | c.250+23C>T | Intron (SNP) | VAF 39/204 reads (19%) | catalogued as rs1486371129; called by muse, mutect2, varscan2
- CCDC149 | c.-76C>A | 5'UTR (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- CCNB2 | c.-12del | 5'UTR (DEL) | VAF 20/192 reads (10%) | called by mutect2, varscan2
- CDKN1A | chr6:36677879 C>A | 5'Flank (SNP) | VAF 30/456 reads (7%) | called by muse, mutect2
- CDKN2A | chr9:21967421 G>T | 3'Flank (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- CHKB | c.447+9C>G | Intron (SNP) | VAF 59/491 reads (12%) | called by muse, mutect2, varscan2
- CIDEA | c.38+155C>A | Intron (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- CREB3L2 | c.319+5409G>A | Intron (SNP) | VAF 14/77 reads (18%) | catalogued as rs1446549444; called by muse, mutect2, varscan2
- CSF2RA | c.-90A>G | 5'UTR (SNP) | VAF 21/370 reads (6%) | called by muse, mutect2
- CYTH4 | c.808+709G>A | Intron (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- CYYR1 | c.-196C>A | 5'UTR (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- DCP1B | c.319+112dup | Intron (INS) | VAF 17/102 reads (17%) | catalogued as rs768665990; called by mutect2, pindel
- DPEP3 | c.-29C>A | 5'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- EIF3IP1 | n.497del | RNA (DEL) | VAF 19/115 reads (17%) | called by mutect2, pindel, varscan2
- EIF5A | c.165+43G>A | Intron (SNP) | VAF 44/314 reads (14%) | catalogued as rs769545622; called by muse, mutect2, varscan2
- ERCC3 | c.28+44G>A | Intron (SNP) | VAF 16/161 reads (10%) | catalogued as rs1397341015; called by muse, mutect2
- EYS | c.1767-8454C>G | Intron (SNP) | VAF 24/482 reads (5%) | called by muse, mutect2
- FMR1 | c.*1053G>T | 3'UTR (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- GABRB1 | c.240+69C>G | Intron (SNP) | VAF 35/261 reads (13%) | called by muse, mutect2, varscan2
- GCLC | c.567-15G>A | Intron (SNP) | VAF 46/403 reads (11%) | called by muse, mutect2, varscan2
- GDF6 | c.*14G>T | 3'UTR (SNP) | VAF 46/326 reads (14%) | catalogued as rs1006798221; called by muse, mutect2, varscan2
- GLRXP3 | n.68G>C | RNA (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- GULP1 | c.610-1871C>T | Intron (SNP) | VAF 45/182 reads (25%) | catalogued as COSV63075326; called by muse, mutect2, varscan2
- HLA-F | c.1036+159G>A | Intron (SNP) | VAF 69/240 reads (29%) | called by muse, mutect2, varscan2
- HLA-J | n.867G>A | RNA (SNP) | VAF 67/625 reads (11%) | called by muse, mutect2, varscan2
- HOXA10 | c.*1101dup | 3'UTR (INS) | VAF 34/188 reads (18%) | called by mutect2, pindel, varscan2
- IL21R | c.-13C>A | 5'UTR (SNP) | VAF 67/258 reads (26%) | catalogued as rs557091943, COSV61973249; called by muse, mutect2, varscan2
- KIAA0586 | c.4384+36G>T | Intron (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- LDHA | chr11:18394602 A>G | 5'Flank (SNP) | VAF 83/340 reads (24%) | catalogued as COSV57039706; called by muse, mutect2, varscan2
- LHX8 | c.-42C>A | 5'UTR (SNP) | VAF 53/432 reads (12%) | called by muse, mutect2, varscan2
- LINC00868 | n.1017G>T | RNA (SNP) | VAF 25/289 reads (9%) | called by muse, mutect2
- LINC01098 | n.512G>T | RNA (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- LINC01591 | n.313A>G | RNA (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3350+2203C>A | Intron (SNP) | VAF 32/247 reads (13%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3216+297A>C | Intron (SNP) | VAF 51/386 reads (13%) | called by muse, mutect2, varscan2
- MGAM | c.4619-13765C>T | Intron (SNP) | VAF 43/293 reads (15%) | catalogued as rs750282712, COSV72074749; called by muse, mutect2, varscan2
- MGAM | c.4619-12532C>A | Intron (SNP) | VAF 123/611 reads (20%) | called by muse, mutect2, varscan2
- MS4A1 | c.280-35C>T | Intron (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- MYO5B | c.*48G>A | 3'UTR (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- NGEF | c.829-10824C>A | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- NMT2 | c.110+13283A>G | Intron (SNP) | VAF 40/453 reads (9%) | called by muse, mutect2
- NXF1 | c.1761-12C>T | Intron (SNP) | VAF 11/244 reads (5%) | called by muse, mutect2
- NXF5 | n.539C>A | RNA (SNP) | VAF 35/278 reads (13%) | called by muse, mutect2, varscan2
- OR2M1P | n.832T>C | RNA (SNP) | VAF 28/321 reads (9%) | catalogued as rs1255839573; called by muse, mutect2
- OR6W1P | n.761T>G | RNA (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- OTX1 | c.98-115T>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
35 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 35 other) are not listed here.
